Somatic mutation profile of tumor specimen C3N-02181-02 (aliquot CPT0168380006) from CPTAC case C3N-02181, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.1 years (19,396 days).
Specimen C3N-02181-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64ce55b4-ac62-49b9-a2d9-83f282299365.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02181-71 (Blood Derived Normal), aliquot CPT0168430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78b2f799-a9f5-4d01-afac-70af7a7f0471

The open-access MAF lists 73 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, 5'UTR 3, 3'UTR 3, Splice Region 2, Nonsense Mutation 2, Splice Site 1, RNA 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC007040.2 | c.69C>G p.V23= | Splice Region (SNP) | VAF 50/393 reads (13%) | catalogued as rs1553426035; called by muse, varscan2
- ARHGAP24 | c.120G>C p.W40C | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM156591; called by muse, mutect2, varscan2
- C5 | c.4166C>A p.S1389Y | Missense Mutation (SNP) | VAF 56/402 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99798986; called by muse, mutect2, varscan2
- CECR2 | c.2882C>T p.P961L (on ENST00000342247 / NM_001290047.2; = p.P778L on NM_001290046.1) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs754756829, COSV52840539; called by muse, mutect2, varscan2
- FAHD2A | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV99271927; called by muse, mutect2, varscan2
- GABRB1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | catalogued as rs562056628, COSV54971426; called by muse, mutect2
- HTR3E | c.445C>T p.R149C (on ENST00000415389 / NM_001256613.1; = p.R164C on NM_182589.2) | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as rs181115598, COSV58946717; called by muse, mutect2, varscan2
- ISM1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 113/484 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768938941, COSV52603958; called by muse, mutect2, varscan2
- JCHAIN | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1209409722, COSV54660150; called by muse, mutect2, varscan2
- KRTCAP3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1439373605, COSV99274997, COSV99275253; called by muse, mutect2
- MTMR6 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67808752; called by muse, mutect2, varscan2
- OR51C1P | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs924750835; called by muse, mutect2, varscan2
- OR5AR1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs143115322; called by muse, mutect2, varscan2
- OR5K4 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100721331; called by muse, mutect2, varscan2
- PCDHGB5 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV53978120; called by muse, mutect2, varscan2
- PTPRC | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs771120252, COSV61408990; called by muse, mutect2, varscan2
- RYR1 | c.4490G>A p.G1497E | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62096928; called by muse, mutect2, varscan2
- SH3TC1 | c.174C>T p.D58= | Splice Region (SNP) | VAF 37/260 reads (14%) | catalogued as rs144449036; called by muse, mutect2, varscan2
- SHISA6 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 101/661 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs1217865843, COSV100603779; called by muse, mutect2, varscan2
- SLC10A2 | c.378C>A p.S126R | Missense Mutation (SNP) | VAF 91/498 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); catalogued as COSV55358670; called by muse, mutect2, varscan2
- SLC17A5 | c.1439G>A p.G480D | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1359538351; called by muse, mutect2, varscan2
- STAM | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs782368686; called by muse, mutect2, varscan2
- STAT1 | c.1873+1G>A p.X625_splice | Splice Site (SNP) | VAF 61/322 reads (19%) | catalogued as COSV63117645; called by muse, mutect2, varscan2
- ZMYM3 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 45/244 reads (18%) | catalogued as COSV58736556; called by muse, mutect2, varscan2
- ADGRG4 | c.5431G>A p.A1811T | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATG4A | c.628A>T p.S210C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP8B4 | c.1013del p.V338Dfs*7 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- CACNA1D | c.4556G>A p.G1519E (on ENST00000350061 / NM_001128840.3; = p.G1539E on NM_000720.4) | Missense Mutation (SNP) | VAF 111/668 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD302 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CGNL1 | c.1436G>T p.S479I | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COBLL1 | c.1786G>A p.V596I (on ENST00000392717; = p.V558I on NM_014900.5) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CS | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CT47B1 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 89/526 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DDX56 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FRG2C | c.816T>G p.S272R | Missense Mutation (SNP) | VAF 60/648 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.975); called by muse, mutect2
- GAREM2 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- MAMLD1 | c.1778C>T p.T593I | Missense Mutation (SNP) | VAF 89/479 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- MUC17 | c.1740G>T p.R580S | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MXRA5 | c.6185G>A p.G2062E | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- MYO3A | c.2682G>T p.M894I | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, varscan2
- NCAPD2 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PADI1 | c.68T>G p.V23G | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- RNLS | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, varscan2
- SAPCD1 | c.368A>G p.Q123R (on ENST00000425424; = p.Q153R on NM_001039651.1) | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SERPINB7 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPIDR | c.2010G>T p.E670D | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- TMEM168 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRGV3 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF546 | c.1310G>A p.G437D | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AATK | c.69C>T p.L23= | Silent (SNP) | VAF 53/232 reads (23%) | called by muse, mutect2, varscan2
- CHM | c.1557T>C p.D519= | Silent (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- COL6A3 | c.3891C>T p.N1297= | Silent (SNP) | VAF 93/567 reads (16%) | catalogued as rs200722316, COSV55081933; ClinVar: likely benign; called by muse, mutect2, varscan2
- ERAP2 | c.1449G>A p.K483= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101163761; called by muse, mutect2, varscan2
- GRID2 | c.141G>A p.A47= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as rs925062774, COSV56173608; called by mutect2, varscan2
- ITLN2 | c.918C>T p.H306= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs748237156, COSV63537936; called by muse, mutect2, varscan2
- LONRF3 | c.225C>T p.D75= | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as rs1368661873; called by muse, mutect2, varscan2
- MECOM | c.303G>A p.R101= (on ENST00000468789 / NM_001105078.4; = p.R289= on NM_004991.4) | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as COSV99244802; called by muse, mutect2, varscan2
- MEGF11 | c.969G>A p.G323= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- MSLNL | c.1776C>T p.D592= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs371406336; called by muse, mutect2, varscan2
- OCA2 | c.1656C>T p.H552= | Silent (SNP) | VAF 106/641 reads (17%) | catalogued as rs777131634, COSV62356597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGR | c.270C>T p.D90= | Silent (SNP) | VAF 55/286 reads (19%) | catalogued as rs561362389, COSV63893848; called by muse, mutect2, varscan2
- SLC1A5 | c.1368C>T p.I456= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as COSV69467527, COSV69467695; called by muse, mutect2, varscan2
- SLC25A52 | c.492T>C p.F164= (on ENST00000672005; = p.F154= on NM_001034172.4) | Silent (SNP) | VAF 53/317 reads (17%) | called by muse, mutect2, varscan2
- SPACA1 | c.153C>T p.T51= | Silent (SNP) | VAF 43/181 reads (24%) | catalogued as COSV52761113; called by muse, mutect2, varscan2
- SULF2 | c.240C>T p.N80= | Silent (SNP) | VAF 54/433 reads (12%) | catalogued as rs774146908, COSV63415943; called by muse, mutect2, varscan2
- CXCL1 | c.*14G>A | 3'UTR (SNP) | VAF 32/220 reads (15%) | catalogued as rs568899629, COSV101203931; called by muse, mutect2, varscan2
- EFHD1 | c.-8C>G | 5'UTR (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- GALNS | c.-25G>A | 5'UTR (SNP) | VAF 44/258 reads (17%) | called by muse, mutect2, varscan2
- MTERF4 | c.*2109A>T | 3'UTR (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- SLC6A4 | c.-118A>G | 5'UTR (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2
- SPG7 | c.377-157_377-154del | Intron (DEL) | VAF 78/482 reads (16%) | called by mutect2, pindel, varscan2
- STX11 | c.*36C>T | 3'UTR (SNP) | VAF 38/221 reads (17%) | called by muse, mutect2, varscan2
- ZNF890P | n.795C>T | RNA (SNP) | VAF 12/154 reads (8%) | catalogued as rs1487250835; called by muse, mutect2, varscan2
